Somatic mutation profile of tumor specimen TCGA-DD-AACO-01A (aliquot TCGA-DD-AACO-01A-11D-A40R-10) from TCGA case TCGA-DD-AACO, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 40.5 years (14,796 days).
Specimen TCGA-DD-AACO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a4489fc-63ed-4cfe-80f9-4fbd594a71e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACO-10A (Blood Derived Normal), aliquot TCGA-DD-AACO-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d04a4590-3a43-47d1-9ddb-2c4cc6960a4d

The open-access MAF lists 48 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 26, Silent 10, Frame Shift Del 4, Splice Site 3, Nonsense Mutation 3, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.4380T>G p.N1460K | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV101330099; called by muse, mutect2, varscan2
- AKAP9 | c.4079del p.N1360Tfs*31 | Frame Shift Del (DEL) | VAF 15/78 reads (19%) | catalogued as rs1465643766; called by mutect2, pindel, varscan2
- ATG2B | c.3716A>G p.H1239R | Missense Mutation (SNP) | VAF 138/352 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99952113; called by muse, mutect2, varscan2
- CACNA1S | c.4396A>T p.T1466S | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100755128; called by muse, mutect2, varscan2
- CNTN3 | c.1364+1G>A p.X455_splice | Splice Site (SNP) | VAF 38/92 reads (41%) | catalogued as rs1449654506, COSV99724985; called by muse, mutect2, varscan2
- DACH1 | c.565A>G p.K189E | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.489); catalogued as COSV100498633; called by muse, mutect2, varscan2
- DAXX | c.298T>G p.L100V | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99802278; called by muse, mutect2, varscan2
- DENND3 | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99371199; called by muse, mutect2, varscan2
- DPF1 | c.961-1G>A p.X321_splice | Splice Site (SNP) | VAF 34/92 reads (37%) | catalogued as COSV99729286; called by muse, mutect2, varscan2
- EIF3J | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV99970731; called by muse, mutect2
- EXO1 | c.1402A>G p.T468A | Missense Mutation (SNP) | VAF 125/364 reads (34%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100799940; called by muse, mutect2, varscan2
- FERD3L | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV51763682, COSV51764415; called by muse, mutect2, varscan2
- IL31 | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV100986577; called by muse, mutect2, varscan2
- IRAK1 | c.2092G>T p.E698* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as COSV100889016; called by muse, mutect2, varscan2
- KRTAP22-1 | c.66T>A p.Y22* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100588932; called by muse, mutect2, varscan2
- LETM2 | c.695T>A p.F232Y (on ENST00000379957 / NM_001286819.2; = p.F137Y on NM_144652.3) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99907484; called by muse, mutect2, varscan2
- MRNIP | c.195A>C p.Q65H | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV99481616; called by muse, mutect2, varscan2
- MUC16 | c.11336C>G p.S3779C | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs772201780, COSV101200307, COSV67486924, COSV67486990; called by muse, mutect2, varscan2
- PALD1 | c.2545C>T p.P849S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.941); catalogued as COSV99698413, COSV99698784; called by muse, mutect2, varscan2
- PHTF1 | c.913G>T p.V305F | Missense Mutation (SNP) | VAF 59/103 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100760134; called by muse, mutect2, varscan2
- PRSS35 | c.668T>G p.L223R | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100864113; called by muse, mutect2, varscan2
- PSMB11 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368929459; called by muse, mutect2, varscan2
- RBSN | c.2010G>T p.E670D | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV99515350; called by muse, mutect2, varscan2
- SGSM1 | c.3047G>A p.G1016E (on ENST00000400359 / NM_001039948.4; = p.G955E on NM_133454.3) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101240366; called by muse, mutect2, varscan2
- SLC9A9 | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV100341477, COSV57230626; called by muse, mutect2, varscan2
- SOX5 | c.40A>G p.M14V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100507269; called by muse, varscan2
- TNNC2 | c.475G>C p.V159L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs777709485, COSV100999460, COSV65332448; called by muse, mutect2, varscan2
- TTLL8 | c.1816A>T p.R606W | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV99838443; called by muse, varscan2
- UBTF | c.1010A>C p.Q337P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100255994; called by muse, mutect2, varscan2
- UNC5A | c.2387A>T p.K796M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99458762; called by muse, mutect2, varscan2
- ZDBF2 | c.3449T>C p.V1150A | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV100985069; called by muse, mutect2, varscan2
- ZNF71 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs774584964, COSV60147820, COSV60148004; called by muse, mutect2, varscan2
- ALB | c.227_232del p.T76_V78delinsI | In Frame Del (DEL) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- ALB | c.1823del p.G608Afs*35 | Frame Shift Del (DEL) | VAF 64/148 reads (43%) | called by mutect2, pindel, varscan2
- CCNO | c.143del p.P48Rfs*46 | Frame Shift Del (DEL) | VAF 50/143 reads (35%) | called by mutect2, pindel, varscan2
- FRMD5 | c.594dup p.A199Sfs*15 | Frame Shift Ins (INS) | VAF 21/51 reads (41%) | called by mutect2, pindel, varscan2
- KEAP1 | c.1557_1560del p.I519Mfs*12 | Frame Shift Del (DEL) | VAF 39/63 reads (62%) | called by mutect2, pindel, varscan2
- TULP2 | c.85-3_99del p.X29_splice | Splice Site (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- ADAD2 | c.669G>T p.L223= (on ENST00000315906 / NM_001145400.2; = p.L295= on NM_139174.4) | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as COSV99235415; called by muse, mutect2, varscan2
- ALDH1L1 | c.1170G>T p.L390= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV99857092; called by muse, mutect2, varscan2
- CCIN | c.873C>T p.G291= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV100631885; called by muse, mutect2, varscan2
- CDK18 | c.1437C>T p.L479= (on ENST00000506784 / NM_212503.3; = p.L449= on NM_002596.4) | Silent (SNP) | VAF 38/127 reads (30%) | catalogued as rs767055966, COSV100774052; called by muse, mutect2, varscan2
- IGF2BP3 | c.135G>A p.P45= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs1469653243, COSV51686795, COSV51689425; called by muse, mutect2, varscan2
- KIF21B | c.4167G>T p.S1389= (on ENST00000422435 / NM_001252100.2; = p.S1376= on NM_017596.4) | Silent (SNP) | VAF 49/91 reads (54%) | catalogued as COSV59765677; called by muse, mutect2, varscan2
- MFSD1 | c.633C>T p.L211= | Silent (SNP) | VAF 31/52 reads (60%) | catalogued as rs147447476; called by muse, mutect2, varscan2
- PLSCR1 | c.837C>A p.I279= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as COSV100678418; called by muse, mutect2, varscan2
- TDRD5 | c.1791A>G p.R597= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV99676526; called by muse, mutect2
- ZCCHC4 | c.13A>C p.R5= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100255342, COSV57181196; called by muse, mutect2, varscan2
